Gene-level copy-number profile of tumor specimen TCGA-D3-A2JF-06A from TCGA case TCGA-D3-A2JF, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 76.1 years (27,799 days).
Specimen TCGA-D3-A2JF-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.886cc2ab-73ca-4ca9-b9fb-237cc84c6665.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D3-A2JF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/6b60d948-7908-4dbb-aef1-d66352be6d4e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 495; copy number 2: 8,009; copy number 3: 29,444; copy number 4: 14,688; copy number 5: 4,323; copy number 6: 2,292; copy number 7: 489; copy number 8: 20; copy number 10: 55.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D3-A2JF-06A-11D-A194-01): tumor purity 0.58, ploidy 3.33, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 564 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:24,319,357–25,113,120, 20 genes, copy number 8 (within-gene range 3–8): GRHL3, STPG1, NIPAL3, RCAN3AS, RCAN3, NCMAP-DT, NCMAP, AL445686.1, Y_RNA, SRRM1, AL445648.1, CLIC4, RNU6-1208P, RUNX3, MIR6731, RUNX3-AS1, AL445471.1, MIR4425, LINC02793, AL050344.1.
- chr6:71,221,457–74,004,812, 55 genes, copy number 10: AL589935.1, AL589935.3, AL589935.2, OGFRL1, AL136164.2, AL136164.1, LINC00472, MIR30C2, AL136164.3, MIR30A, LINC01626, AL035467.2, AL035467.1, KRT19P1, RNU4-66P, RIMS1, AL035633.1, FO393414.2, FO393414.1, FO393414.3, KCNQ5, MIR4282, KNOP1P4, PGAM1P10, KCNQ5-AS1, RBPMS2P1, KHDC1P1, AL365232.1, KHDC1L, KHDC1, AC019205.1, RPSAP41, EIF3EP1, SDCBP2P1, PAICSP3, DPPA5, KHDC3L, OOEP, OOEP-AS1, RPL39P3, RPS6P8, DDX43, CGAS, MTO1, RNU6-975P, RN7SL827P, EEF1A1, AL121972.1, AL603910.1, SLC17A5, RPS27P15, AL590428.1, CD109, AL590552.1, TXNP7.
- chr11:167,784–8,268,716, 440 genes, copy number 7 (broad region; genes not listed).
- chr22:19,447,893–20,390,758, 49 genes, copy number 7 (within-gene range 2–7): AC000068.1, UFD1, AC000068.3, AC000068.2, CDC45, AC000082.1, CLDN5, LINC00895, AC000077.1, AC000067.1, SEPTIN5, AC000093.1, GP1BB, TBX1, GNB1L, AC000089.1, RTL10, TXNRD2, AC000078.1, COMT, MIR4761, ARVCF, TANGO2, MIR185, AC006547.1, AC006547.3, Metazoa_SRP, DGCR8, MIR3618, MIR1306, AC006547.2, TRMT2A, MIR6816, RANBP1, SNORA77B, ZDHHC8, CCDC188, AC007663.2, LINC00896, RTN4R, MIR1286, AC007663.1, DGCR6L, AC007663.4, AC007663.3, FAM230G, AC007731.2, AC007731.5, USP41.

Autosomal genes at a single copy (total copy number 1): 495. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
